Somatic mutation profile of tumor specimen TCGA-KK-A7AP-01A (aliquot TCGA-KK-A7AP-01A-12D-A33T-08) from TCGA case TCGA-KK-A7AP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,403 days).
Specimen TCGA-KK-A7AP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f7f38f-8e78-45a3-99f2-84e8ff3f5be3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AP-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AP-11A-21D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6006532a-6a92-4dd7-afce-e0759f996f6a

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 3, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.1663G>C p.A555P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV99922321; called by muse, mutect2, varscan2
- CLBA1 | c.954del p.L319Sfs*84 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | catalogued as COSV66348447; called by mutect2, pindel, varscan2
- DNAH10 | c.9364C>G p.L3122V (on ENST00000409039; = p.L3061V on NM_207437.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0.264); catalogued as COSV101292386; called by muse, mutect2, varscan2
- EDRF1 | c.2543G>T p.G848V (on ENST00000356792 / NM_001202438.2; = p.G814V on NM_015608.2) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380958141, COSV100523637; called by muse, mutect2, varscan2
- EPPK1 | c.6538C>G p.Q2180E | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs782607368, COSV101599889; called by muse, mutect2, varscan2
- FAHD2B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426534573, COSV55631488; called by muse, mutect2, varscan2
- KIAA1549L | c.3298C>T p.R1100W (on ENST00000321505; = p.R1397W on NM_012194.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757475102, COSV55775832, COSV55777990; called by muse, mutect2, varscan2
- KMT2D | c.10951C>A p.Q3651K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56423741, COSV99983663; called by muse, mutect2
- LCN15 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752730383, COSV100293483; called by muse, varscan2
- LRRC4C | c.951A>T p.K317N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs766338226, COSV99538834; called by muse, mutect2, varscan2
- MAP2 | c.4228G>C p.E1410Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV52290149, COSV52309077; called by muse, mutect2, varscan2
- MYLK3 | c.604del p.E202Rfs*97 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV67364903; called by mutect2, pindel, varscan2
- PPP1R15A | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745899453, COSV99566134; called by muse, mutect2, varscan2
- PTPRM | c.2226A>C p.K742N | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100158513; called by muse, mutect2, varscan2
- SERGEF | c.353A>G p.E118G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99787460; called by muse, mutect2
- SLC12A5 | c.1684C>T p.L562F (on ENST00000454036 / NM_001134771.2; = p.L539F on NM_020708.5) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV99716379; called by muse, mutect2
- SLC34A1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577273266, COSV100184021; called by muse, mutect2, varscan2
- SMCR8 | c.1502T>G p.V501G | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100329200; called by muse, mutect2, varscan2
- TUBGCP3 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1011473425, COSV99997010; called by muse, mutect2, varscan2
- UNC119 | c.610+7G>T | Splice Region (SNP) | VAF 37/45 reads (82%) | catalogued as COSV99971737; called by muse, mutect2, varscan2
- YBX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as COSV100172142; called by muse, mutect2, varscan2
- ZAN | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs529432579, COSV61806521, COSV61814249; called by muse, mutect2
- CNKSR3 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- LGALS13 | c.56del p.C19Sfs*2 | Frame Shift Del (DEL) | VAF 39/139 reads (28%) | called by mutect2, pindel, varscan2
- ACACB | c.7053T>C p.S2351= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100623077; called by muse, mutect2, varscan2
- ARID2 | c.567C>T p.H189= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs1298719413, COSV100536491; called by muse, mutect2, varscan2
- CACNA1C | c.1803G>A p.L601= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100219973, COSV59777043; called by muse, mutect2, varscan2
- FAT4 | c.5214A>T p.P1738= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as COSV100629169; called by muse, mutect2, varscan2
- MUC17 | c.7575G>A p.T2525= | Silent (SNP) | VAF 186/410 reads (45%) | catalogued as rs202162190; called by muse, mutect2, varscan2
- MYO15A | c.6786C>T p.R2262= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs372462304; called by muse, mutect2, varscan2
- SPTA1 | c.5241G>T p.G1747= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV100935172; called by muse, mutect2, varscan2
- VAV1 | c.2175A>C p.G725= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100409238; called by muse, mutect2, varscan2
- DCHS2 | n.1729G>A | RNA (SNP) | VAF 31/81 reads (38%) | catalogued as COSV59742447; called by muse, mutect2, varscan2
